Surgical pathology report (de-identified scan), TCGA case TCGA-61-1734, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1734-01B (Primary Tumor).

FINAL DIAGNOSIS:

PARTS 1

AND 2: OVARIES, LEFT AND RIGHT, BILATERAL SALPINGO-OOPHORECTOMY –

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS CYSTADENOCARCINOMA INVOLVING RIGHT AND LEFT OVARIES.
- B. LEFT OVARIAN MASS MEASURES 15 CM IN GREATEST DIMENSION.
- C. RIGHT OVARIAN MASS MEASURES 11 CM IN GREATEST DIMENSION.
- D. OVARIAN SURFACE INVOLVEMENT IS IDENTIFIED (SLIDE 1N).
- E. LYMPHOVASCULAR INVASION IS IDENTIFIED (SLIDE 2K).
- F. NON-NEOPLASTIC OVARIAN PARENCHYMA WITH PHYSIOLOGIC CHANGES BILATERALLY.

PART 3: UTERUS WITH BILATERAL FALLOPIAN TUBES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (158 G) –

- A. CERVIX WITH CHRONIC CERVICITIS AND REACTIVE EPITHELIAL ATYPIA.
- B. SECRETORY ENDOMETRIUM.
- C. ENDOMETRIAL POLYP.
- D. LEIOMYOMAS, UP TO 1.5 CM.
- E. FALLOPIAN TUBES, LEFT AND RIGHT, WITH NO SIGNIFICANT PATHOLOGIC CHANGES.

PART 4: LYMPH NODES, RIGHT EXTERNAL ILIAC, DISSECTION –
THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 5: LYMPH NODES, RIGHT OBTURATOR, BIOPSY –
THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 6: LYMPH NODES, RIGHT COMMON ILIAC, BIOPSY –
ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY –
ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 8: APPENDIX, APPENDECTOMY –
APPENDIX, NEGATIVE FOR TUMOR.

PART 9: LYMPH NODES, LEFT EXTERNAL ILIAC, BIOPSY –
THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 10: LYMPH NODES, LEFT OBTURATOR, BIOPSY –
THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 11: LYMPH NODE, LEFT COMMON ILIAC, BIOPSY –
ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 12: POSTERIOR CUL-DE-SAC, BIOPSY –
GRANULATION TISSUE, NEGATIVE FOR TUMOR.

PART 13: BLADDER FLAP, BIOPSY –
FIBROADIPOSE AND CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 14: SOFT TISSUE, LEFT PARACOLIC GUTTER, BIOPSY –
FIBROADIPOSE AND CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 15: SOFT TISSUE, RIGHT PARACOLIC GUTTER, BIOPSY –
FIBROADIPOSE AND CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 16: SOFT TISSUE, SUB-DIAPHRAGM, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 17: OMENTUM, OMENTECTOMY –
A. FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
B. TWO (2) LYMPH NODES IDENTIFIED, NEGATIVE FOR TUMOR (0/2).

PART 18: SOFT TISSUE, SIGMOID COLON ADHESION, BIOPSY –
FIBROVASCULAR CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file cca23b77-fdef-4603-bcdb-064864a3f897 (TCGA-61-1734.32D02AA2-1C81-417B-87A8-A5ED4035F5C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).